Somatic mutation profile of tumor specimen TCGA-A4-8310-01A (aliquot TCGA-A4-8310-01A-11D-2396-08) from TCGA case TCGA-A4-8310, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 58.3 years (21,312 days).
Specimen TCGA-A4-8310-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3a20c65-7c13-4cd2-9d85-9eb7735c3f09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-8310-10A (Blood Derived Normal), aliquot TCGA-A4-8310-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11ca2e28-84cc-4ee5-bf84-b2a0595f95f2

The open-access MAF lists 69 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 18, Nonsense Mutation 3, Frame Shift Ins 3, Frame Shift Del 1, 3'UTR 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR2A | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs760629539, COSV54019370; called by muse, mutect2, varscan2
- ADAMTS16 | c.2512C>G p.L838V | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56979136; called by muse, mutect2
- ALG9 | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as rs1317581288, COSV67643620; called by muse, mutect2, varscan2
- APOL6 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV68749386; called by muse, mutect2, varscan2
- ARFGEF2 | c.3914C>A p.P1305H | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64210661; called by muse, mutect2, varscan2
- ATP7B | c.3988A>C p.I1330L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV54435410; called by muse, mutect2, varscan2
- BRINP3 | c.1410C>G p.S470R | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.154); catalogued as COSV66514388, COSV66515243; called by muse, mutect2, varscan2
- CLPTM1L | c.1297A>G p.I433V | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV57989452; called by muse, mutect2, varscan2
- CLUH | c.3447C>A p.H1149Q (on ENST00000435359; = p.H1188Q on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV70927872; called by muse, mutect2, varscan2
- CUBN | c.628T>C p.C210R | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64708460; called by muse, mutect2, varscan2
- CXorf38 | c.307T>C p.C103R | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV59947276; called by muse, mutect2, varscan2
- DDAH2 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as rs752006519, COSV65383552; called by muse, mutect2, varscan2
- DENND4B | c.398T>A p.L133Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57841198; called by muse, mutect2, varscan2
- ESD | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66339763; called by muse, mutect2, varscan2
- FBN2 | c.5533C>G p.L1845V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV52494497; called by muse, mutect2, varscan2
- GOLGB1 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV61462066, COSV61469579; called by muse, mutect2, varscan2
- GSTA1 | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 103/316 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58014541; called by muse, mutect2, varscan2
- GTF2B | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65136663; called by muse, mutect2, varscan2
- HMGB2 | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV56633200; called by muse, mutect2, varscan2
- IBTK | c.3280A>C p.I1094L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV60391022; called by muse, mutect2, varscan2
- ICOS | c.572A>C p.K191T | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV57029294; called by muse, mutect2, varscan2
- IDE | c.1874A>G p.Y625C | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as COSV56421646; called by muse, mutect2, varscan2
- IGFBP4 | c.737A>G p.E246G | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV54096673; called by muse, mutect2, varscan2
- LDLRAP1 | c.518A>G p.Q173R | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV65473154; called by muse, mutect2, varscan2
- NCKAP5 | c.434A>C p.K145T | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV58428916; called by muse, mutect2, varscan2
- NCOA6 | c.3199A>G p.R1067G | Missense Mutation (SNP) | VAF 202/327 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62861494; called by muse, mutect2, varscan2
- NEB | c.9623T>C p.L3208S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50816705; called by muse, mutect2, varscan2
- OS9 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 65/239 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs752983128, COSV57782024; called by muse, mutect2, varscan2
- PCNX2 | c.4235A>G p.N1412S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.263); catalogued as rs1436896662, COSV50783140; called by muse, mutect2, varscan2
- PCSK5 | c.4726T>C p.C1576R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV70447462; called by muse, mutect2, varscan2
- PDE5A | c.1655A>T p.Q552L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV53345766; called by muse, mutect2, varscan2
- PDZD2 | c.2314C>A p.L772M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56851525; called by muse, mutect2, varscan2
- PITPNM1 | c.2239A>G p.K747E | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV62707443; called by muse, mutect2, varscan2
- PLK2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); catalogued as rs749015923; called by muse, mutect2
- PPIA | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as COSV63533897; called by muse, mutect2, varscan2
- PPP6R1 | c.950T>A p.L317* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV69799310; called by muse, mutect2, varscan2
- RUFY1 | c.335A>G p.E112G | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100105566, COSV60158491; called by muse, mutect2, varscan2
- SLC12A4 | c.1811C>T p.T604I | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV50452123; called by muse, mutect2, varscan2
- SLC22A8 | c.91A>G p.M31V | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV60323808; called by muse, mutect2, varscan2
- SNX25 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV53011833, COSV53012284; called by muse, mutect2, varscan2
- STK24 | c.992dup p.S332Qfs*2 | Frame Shift Ins (INS) | VAF 36/108 reads (33%) | catalogued as rs758627015; called by mutect2, pindel, varscan2
- TNIP2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs150823075; called by muse, mutect2, varscan2
- WASHC5 | c.1136A>C p.H379P | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59194250; called by muse, mutect2, varscan2
- XYLT1 | c.2707G>T p.E903* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV54475980, COSV54477959; called by muse, mutect2
- ACMSD | c.983dup p.L328Ffs*4 | Frame Shift Ins (INS) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- ASAP3 | c.381_382dup p.L128Pfs*5 | Frame Shift Ins (INS) | VAF 65/201 reads (32%) | called by mutect2, pindel, varscan2
- CCDC18 | c.1637del p.A546Vfs*9 (on ENST00000343253 / NM_001306076.1; = p.A547Vfs*9 on NM_206886.4) | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- FBXO42 | c.1993_1999dup p.S667Ifs*2 | Nonsense Mutation (INS) | VAF 48/193 reads (25%) | called by mutect2, varscan2
- HECTD2 | c.1432+2dup p.X478_splice | Splice Site (INS) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- ACLY | c.3150A>G p.E1050= | Silent (SNP) | VAF 39/165 reads (24%) | catalogued as COSV59861446; called by muse, mutect2, varscan2
- BCOR | c.1719C>A p.A573= | Silent (SNP) | VAF 29/34 reads (85%) | catalogued as COSV60700742; called by muse, mutect2, varscan2
- BFAR | c.858G>T p.L286= | Silent (SNP) | VAF 152/265 reads (57%) | catalogued as COSV55492584; called by muse, mutect2, varscan2
- CSNK1D | c.1230G>A p.Q410= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV53923046; called by muse, mutect2, varscan2
- CYP11B1 | c.1032C>T p.S344= | Silent (SNP) | VAF 65/158 reads (41%) | catalogued as COSV52825057; called by muse, mutect2, varscan2
- DAB2 | c.12A>G p.E4= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV57912485; called by muse, mutect2, varscan2
- DNMT3B | c.609G>A p.P203= | Silent (SNP) | VAF 47/78 reads (60%) | catalogued as rs376501500; called by muse, mutect2, varscan2
- DNPEP | c.1245C>T p.L415= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV56110142; called by muse, mutect2, varscan2
- GJB1 | c.807C>T p.T269= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs750620543, COSV62139535; ClinVar: likely benign; called by muse, mutect2, varscan2
- GOLPH3L | c.345T>A p.G115= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV55044878; called by muse, mutect2, varscan2
- HNRNPK | c.651C>A p.P217= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV61088325; called by muse, mutect2, varscan2
- MYO1E | c.855G>C p.L285= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV55682774; called by muse, mutect2, varscan2
- NCAPD2 | c.3637C>A p.R1213= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV57520509; called by muse, mutect2, varscan2
- NDEL1 | c.306T>C p.S102= | Silent (SNP) | VAF 54/107 reads (50%) | catalogued as COSV55325120; called by muse, mutect2, varscan2
- RGS17 | c.540T>A p.T180= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV52806168, COSV99242795; called by muse, mutect2, varscan2
- SERPINA10 | c.141G>A p.E47= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV56227512; called by muse, mutect2
- SLC7A2 | c.1641G>A p.Q547= (on ENST00000494857 / NM_001370338.1; = p.Q586= on NM_003046.6) | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV50247862; called by muse, mutect2, varscan2
- SNAPC4 | c.3804C>A p.A1268= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV53730907; called by muse, mutect2
- CPLANE1 | c.*4606G>A | 3'UTR (SNP) | VAF 22/60 reads (37%) | catalogued as COSV57052845; called by muse, mutect2, varscan2
- RORA | c.197-25034A>G | Intron (SNP) | VAF 77/152 reads (51%) | catalogued as COSV55035848; called by muse, mutect2, varscan2
